Somatic mutation profile of tumor specimen 0DW6BQ from CCDI case PBCNRG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 6.3 years (2,319 days).
Specimen 0DW6BQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b51034d-bce2-4b0b-8932-622d5e623e01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW6B2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49bcb7f4-550c-44a9-a0ff-238062c2546e

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L11 | c.539G>A p.R180Q (on ENST00000393256 / NM_138621.5; = p.R120Q on NM_006538.5) | Missense Mutation (SNP) | VAF 48/688 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs185078669, COSV58029760; called by muse, mutect2
- GON4L | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 30/842 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV55190925; called by muse, mutect2
- MEIS3 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV58984982; called by muse, mutect2
- PNPLA8 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 297/512 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs942694872, COSV57553843; called by muse, varscan2
- RBFOX2 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 34/672 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as rs753139342; called by muse, mutect2
- RUFY4 | c.1483C>G p.R495G | Missense Mutation (SNP) | VAF 95/889 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60247470; called by muse, mutect2, varscan2
- TP53 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 168/338 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52740649, COSV52756528, COSV52999219; called by muse, mutect2, varscan2
- ATP1A1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 64/592 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CRYBG3 | c.5932G>T p.D1978Y | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZDBF2 | c.6511C>A p.Q2171K | Missense Mutation (SNP) | VAF 366/691 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2A1 | c.2175C>T p.A725= | Silent (SNP) | VAF 39/672 reads (6%) | catalogued as rs1332742510, COSV100706824, COSV100707210; ClinVar: likely benign; called by muse, mutect2
- CLINT1 | c.1053C>T p.G351= | Silent (SNP) | VAF 131/608 reads (22%) | catalogued as rs1192476710; called by muse, mutect2, varscan2
- DLGAP4 | c.198G>A p.P66= | Silent (SNP) | VAF 358/645 reads (56%) | catalogued as rs777239234, COSV59414565, COSV59423956; called by muse, mutect2, varscan2
- LRBA | c.2898T>C p.N966= | Silent (SNP) | VAF 28/906 reads (3%) | called by muse, mutect2
- PASD1 | c.2133C>T p.C711= | Silent (SNP) | VAF 155/686 reads (23%) | catalogued as rs756636815; called by muse, mutect2, varscan2
- TRPC6 | c.*37C>T | 3'UTR (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
